Surgical pathology report (de-identified scan), TCGA case TCGA-IC-A6RF, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-IC-A6RF-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: DISTAL LEFT MAINSTEM, BIOPSY:

- A. SUBOPTIMAL, MINUTE FRAGMENT CONSISTS OF BRONCHIAL MUCOSA.
- B. NO TUMOR SEEN.

PART 2: BRONCHUS INTERMEDIUS BIOPSY:

- A. MINUTE FRAGMENT OF BRONCHIAL MUCOSA WITH MINIMAL INFLAMMATION.
- B. NO TUMOR SEEN.

PART 3: LEFT GASTRIC TISSUE, BIOPSY:

FRAGMENT OF FIBROUS-ADIPOSE TISSUE WITH SINGLE LYMPH NODE NEGATIVE FOR MALIGNANCY (0/1).

PART 4: PARAESOPHAGEAL LYMPH NODE NEAR PERICARDIUM, EXCISION:

NO TUMOR SEEN IN TWO LYMPH NODES (0/2).

PART 5: PARAESOPHAGEAL LYMPH NODE, EXCISION:

NO TUMOR SEEN IN SINGLE LYMPH NODE (0/1).

PART 6: PARAESOPHAGEAL LYMPH NODE NEAR CARINA:

NO TUMOR SEEN IN THREE LYMPH NODES (0/3).

PART 7: PARAESOPHAGEAL LYMPH NODE NEAR LEFT MAIN BRONCHUS, EXCISION:

NO TUMOR CELLS IN A SINGLE LYMPH NODE (0/1).

PART 8: ESOPHAGUS, ESOPHAGECTOMY:

- A. WELL DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH EXOPHYTIC/ PAPILLARY GROWTH PATTERN, MULTIFOCAL (TWO POLYPOID/EXOPHYTIC MASSES IDENTIFIED 3.5 CM AND 1.5 CM IN GREATEST DIMENSION RESPECTIVELY).

- a. TUMORS INVADE SUPERFICIAL DUPLICATED LAYERS OF MUSCULARIS MUCOSAE (T1a).
- b. NO ANGIOLYMPHATIC INVASION PRESENT.
- c. NO PERINEURAL INVASION IDENTIFIED.
- d. NO TUMOR SEEN IN TWO LYMPH NODES (0/2).
- e. PROXIMAL AND GASTRIC RESECTION MARGINS (see parts 9, 10, 12 and 13) AND ADVENTITIAL MARGINS FREE OF TUMOR.
- f. PATHOLOGIC STAGE (AJCC 7TH Ed): pT1b, N0.

- B. UNINVOLVED ESOPHAGEAL MUCOSA WITH:

- a. MARKED AND DIFFUSE ACANTHOSIS.
- b. FOCAL BARRETT'S MUCOSA IDENTIFIED AT ESOPHAGEAL-GASTRIC JUNCTION.

- C. UNINVOLVED GASTRIC MUCOSA WITH OXYNTIC CELLS HYPERPLASIA AND FOCAL GLANDS CYSTIC DILATATION; CHANGES SUGGESTIVE OF PROTON PUMP INHIBITOR THERAPY (PPIT).

PART 9: ESOPHAGEAL MARGIN, RESECTION:

- A. ESOPHAGEAL MARGIN NEGATIVE FOR MALIGNANCY.
- B. ESOPHAGEAL EPITHELIUM WITH REACTIVE CHANGES.

PART 10: MOST PROXIMAL MARGIN, RESECTION:

FRAGMENT OF ESOPHAGUS NEGATIVE FOR MALIGNANCY, WITH FOCAL CHRONIC INFLAMMATION.

PART 11: GASTROESOPHAGEAL FAT, RESECTION:

FRAGMENTS OF ADIPOSE TISSUE WITH TWELVE LYMPH NODES NEGATIVE FOR MALIGNANCY (0/12).

PART 12: EEA FINAL MARGIN, RESECTION:

- A. FRAGMENT OF GASTRIC OXYNTIC MUCOSA, NEGATIVE FOR MALIGNANCY, WITH FOCAL CHRONIC INFLAMMATION.
- B. SEPARATE FRAGMENT OF ESOPHAGUS NEGATIVE FOR MALIGNANCY.

PART 13: FINAL GASTRIC MARGIN, RESECTION:

- A. FRAGMENT OF GASTRIC OXYNTIC MUCOSA NEGATIVE FOR MALIGNANCY.
- B. DIFFUSE MUCOSA CONGESTION.

ICD-O-3

Carcinoma, squamous
cell NOS 8670/3

C62.0

Site Middle third
esophagus @15.5

path Thoroughly resected
@15.1
JW

[page 2 of 2]
CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS****----- MACROSCOPIC -----****SPECIMEN TYPE:****TUMOR SITE:****TUMOR SIZE:**

Esophagogastrectomy
Midthoracic esophagus (10-15cm from EGJ)
Greatest dimension: 3.5 cm
Additional dimensions: 2.5 x 0.3 cm

----- MICROSCOPIC -----**HISTOLOGIC TYPE:****HISTOLOGIC GRADE:****PATHOLOGIC STAGING (pTNM)**

Squamous cell carcinoma
G1

m (multiple primary tumors)

pT1a

pN0

Number of lymph nodes examined: 22

Number of lymph nodes involved: 0

17 or more regional lymph nodes were identified

pM Not applicable

No prior treatment

PRIOR TREATMENT:**MARGINS**

Proximal margin uninvolved by invasive carcinoma

Proximal margin uninvolved by dysplasia

Proximal margin uninvolved by intestinal metaplasia

Distal margin uninvolved by invasive carcinoma

Distal margin uninvolved by dysplasia

Distal margin uninvolved by intestinal metaplasia

Circumferential (adventitial) margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 15 mm

Specify margin: proximal resection margin

ANGIOLYMPHATIC INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Intestinal metaplasia (Barrett's esophagus)

High grade dysplasia

Tumor site:

Comment:

two lesions were identified : one cm 3.5 at midesophagus 7.0 cm far from the GE junction and the second lesion (1.5 cm) located 5.5 cm far from GEJ.

Criteria	W 6/20/13	Yes	No
Concurrent Primary Note			

Source: NCI Genomic Data Commons file 13568569-df99-4995-8963-2a3ba6784d40 (TCGA-IC-A6RF.8E288022-B4B3-46F1-84A1-4F1ECC8ABB7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).